Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A23V, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A23V-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

ICD-0-3

Dedifferentiated liposarcoma 8858/3

Site: retroperitoneum C48.0

lu 4/21/11

....

Clinical Diagnosis & History:

Retroperitoneal liposarcoma, for resection.

Specimens Submitted:

- 1: SP: Retroperitoneal sarcoma, 2nd & 3rd portion of duodenum and right colon
- 2: SP: Subcutaneous fat (
- 3: SP: Proximal small bowel
- 4: SP: Gallbladder
- 5: SP: Superior mesenteric vein nodule

DIAGNOSIS:

- 1) SOFT TISSUE, 2ND AND 3RD PORTION OF DUODENUM, PORTION OF PANCREAS; RIGHT COLON; EXCISION:
- DEDIFFERENTIATED LIPOSARCOMA, PRESENT AS MULTIPLE NODULES (13 CM IN AGGREGATE) INVOLVING MESENTERIC/SUBSEROSAL FAT OF DUODENUM AND LARGE BOWEL.
- THE TUMOR EXTENDS TO THE DEEP MARGIN.
- THE TUMOR INVOLVES THE DUODENAL WALL AND ENCASES THE PORTION OF PANCREAS.
- 2) ADIPOSE TISSUE, SUBCUTANEOUS; BIOPSY:
- BENIGN ADIPOSE TISSUE.
- 3) SMALL BOWEL, PROXIMAL; EXCISION:
- BENIGN SMALL BOWEL WALL WITH MODERATE ACUTE SEROSITIS.
- 5) GALLBLADDER; CHOLECYSTECTOMY:
- BENIGN GALLBLADDER.
- 5) SOFT TISSUE, SUPERIOR MESENTERIC VEIN NODULE; EXCISION:
- WELL-DIFFERENTIATED LIPOSARCOMA, SCLEROSING-TYPE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

** Continued on next page **

[page 2 of 4]
Gross Description:

1) The specimen is received fresh, labeled "Retroperitoneal sarcoma, 2nd and 3rd portion of duodenum and right colon". It consists of a segment of duodenum, 2nd and 3rd portions, measuring 15 cm in length. Both margins are stapled. The proximal margin measures 5 cm in circumference. The distal margin measures 6 cm in circumference. Between the 2nd and 3rd portions of the duodenum at the superior margin, a small fragment of pancreatic tissue is recognized, measuring 2 x 1 x 0.5 cm. Attached to the duodenal wall, covered by the duodenal serosa on the superior aspect of the 3rd portion of the duodenum, there is a multinodular, rubbery tumor, measuring 4 x 3 x 2.5 cm. The tumor has an attached 0.5 cm pedicle to the duodenal wall and is located 2 cm from the distal duodenal margin. The second multinodular tumor covered on the anterior aspect by the peritoneum and located 5 cm from the distal surgical margin is seen. This tumor is composed of multiple nodules, ranging in size from 1 to 3.5 cm in diameter. On the right side, 5 cm from the duodenal angle, there is a segment of ascending colon and terminal ileum. The terminal ileum measures 2.5 cm in length. The proximal surgical margin measures 4 cm in circumference. The ascending colon measures 15 cm in length. The distal surgical margin measures 9 cm in circumference. The appendix is not identified. The pericolic fat measures up to 5 cm in width. The surgical margin is inked: superior-blue, deep-black, inferior-red, lateral-green. The duodenum is opened, revealing an unremarkable duodenal mucosa. The colon is opened to reveal unremarkable tan-pink mucosa. Serial sectioning of the specimen shows that the nodules adjacent to the distal duodenum have a tan-pink appearance. The nodules located retroperitoneal show a variegated appearance. Some have a white-yellow appearance. They measure from 1.0 x 0.3 cm in diameter and are located 0.1 cm from the deep margin. One of the nodules located 3 cm from the deep margin showed a tan-pink appearance with hemorrhagic areas. This nodule measures 3.5 cm and has a soft consistency. Sections are taken to . Photographs are taken.

Summary of Sections:

DPM - Duodenal proximal margin
DDM - Duodenal distal margin
TD - Tumor at the distal margin
RT - Retroperitoneal tumor
IM - Inner margin
CM - Colonic margin
D - Duodenum
C - Colon
CNL - Pericolic lymph node

2) The specimen is received fresh, labeled "Subcutaneous fat". It consists of multiple irregular pieces of fatty tissue, measuring 3 x 3 x 0.25 cm. The specimen is submitted for representative sections are submitted for permanent sections.

** Continued on next page **

[page 3 of 4]
Summary of Sections:

Page 3 of 4

U - Undesignated

#3). Specimen received in formalin labeled "Proximal small bowel". It consists of a single fragment of small bowel with attached scanty amount of mesenteric adipose tissue. The bowel measures 5 cm length and 3.5 cm in greatest diameter. The serosa is tan and smooth. Upon opening the intestinal wall measures 0.5 cm in thickness. The mucosa is tan and unremarkable. Representative sections are submitted.

Cassette summary:

SM-surgical margins.

I-intestine.

#4). specimen received formalin labeled "Gallbladder". It consists of an a club-shaped gallbladder measuring 10 x 3 x 2.5 cm. The serosa is tan and smooth. Upon opening the lumen contains green bile. No calculi were identified. The wall measures 0.2 cm in thickness. The mucosa is velvety and grossly unremarkable. Representative sections are submitted.

Cassette summary:

U-undesignated.

#5). Specimen received in formalin labeled "Superior mesenteric vein nodule". It consists of a nodular fibromembranous tissue measuring 1 x 1 x 0.6 cm. The nodule was bisected and entirely submitted.

Cassette summary:

U-undesignated.

Summary of Sections:

Part 1: SP: Retroperitoneal sarcoma, 2nd & 3rd portion of duodenum and right colon

Block	Sect.	Site	PCs
1		c	1
1		cm	1
1		cnl	1
1		d	1
1		ddm	1
1		dpm	1
1		i	1
3		LN	14
8		rt	8
3		td	3

Part 2: SP: Subcutaneous fat

** Continued on next page **

[page 4 of 4]
Block Sect. Site PCs
2 u 2

Part 3: SP: Proximal small bowel

Block Sect. Site PCs
1 i 2
1 sm 2

Part 4: SP: Gallbladder

Block Sect. Site PCs
1 u 3

Part 5: SP: Superior mesenteric vein nodule (

Block Sect. Site PCs
1 u 2

** End of Report **

Source: NCI Genomic Data Commons file e5c8f8aa-eea5-4c86-98c9-ec4be2551d36 (TCGA-DX-A23V.BA4B87C2-DF4C-43C9-8F52-4630D758FEA4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).